Somatic mutation profile of tumor specimen MP2PRT-PASRTJ-TMP1-A (aliquot MP2PRT-PASRTJ-TMP1-A-3-0-D-A79Q-36) from MP2PRT case MP2PRT-PASRTJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Precursor B-cell lymphoblastic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (595 days).
Specimen MP2PRT-PASRTJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 025dda92-3029-4803-a90a-fb884a1dfb11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASRTJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASRTJ-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9202fd15-a5f9-466d-8fec-2dcb7f3fa14c

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 4, Frame Shift Del 1, 3'UTR 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KSR2 | c.2374G>A p.V792I | Missense Mutation (SNP) | VAF 54/381 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.533); catalogued as rs763587643; called by muse, mutect2, varscan2
- PSG6 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 40/581 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs750179815, COSV51834910; called by muse, mutect2
- ETV6 | c.1033_1034insGG p.V345Gfs*27 | Frame Shift Ins (INS) | VAF 11/101 reads (11%) | called by mutect2, pindel, varscan2
- FBN3 | c.4193A>G p.D1398G | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.207); called by muse, mutect2
- IGLV4-69 | c.357_359delinsCCCCCC | In Frame Ins (INS) | VAF 24/169 reads (14%) | called by pindel, varscan2*
- MYCN | c.1160_1166del p.N387Rfs*24 | Frame Shift Del (DEL) | VAF 125/330 reads (38%) | called by mutect2, pindel, varscan2
- PRDM14 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 34/498 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- OR2M3 | c.219C>T p.L73= | Silent (SNP) | VAF 33/642 reads (5%) | called by muse, mutect2
- SLC27A5 | c.942G>A p.Q314= | Silent (SNP) | VAF 12/397 reads (3%) | called by muse, mutect2
- UBXN10 | c.645C>T p.F215= | Silent (SNP) | VAF 19/417 reads (5%) | called by muse, mutect2
- USP11 | c.1038C>T p.L346= (on ENST00000218348; = p.L303= on NM_001371072.1) | Silent (SNP) | VAF 18/604 reads (3%) | called by muse, mutect2
- ZFP69 | c.435C>T p.P145= | Silent (SNP) | VAF 17/302 reads (6%) | catalogued as rs1310229087, COSV101018415; called by muse, mutect2
- ABO | c.*24G>A | 3'UTR (SNP) | VAF 17/490 reads (3%) | called by muse, mutect2
